Somatic mutation profile of tumor specimen TCGA-EI-6506-01A (aliquot TCGA-EI-6506-01A-11D-1733-10) from TCGA case TCGA-EI-6506, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.3 years (28,587 days).
Specimen TCGA-EI-6506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f09e6b28-b6e2-4e03-8d82-4ae8ab169f84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6506-10A (Blood Derived Normal), aliquot TCGA-EI-6506-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63eeb152-109e-4db6-8898-c8e1fc6dce2a

The open-access MAF lists 140 somatic variants for this specimen: 108 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 30, Frame Shift Del 5, Nonsense Mutation 4, In Frame Del 3, Splice Site 2, Frame Shift Ins 1, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3566A>G p.Y1189C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs1308685899, COSV60688739; called by muse, mutect2, varscan2
- ADAD1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV56644803; called by muse, mutect2, varscan2
- ADAM17 | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.052); catalogued as COSV100176325; called by muse, mutect2, varscan2
- ADCY2 | c.2165C>G p.S722* | Nonsense Mutation (SNP) | VAF 38/152 reads (25%) | catalogued as COSV57881866; called by muse, mutect2, varscan2
- APC | c.3845C>A p.S1282* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as CM106372, COSV57326418, COSV57344541; called by muse, mutect2, varscan2
- ARHGEF9 | c.575G>C p.W192S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV53640263; called by muse, mutect2
- ASPH | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.067); catalogued as COSV62860161; called by muse, mutect2, varscan2
- ASTN2 | c.1546C>A p.Q516K (on ENST00000313400 / NM_001365069.1; = p.Q465K on NM_014010.5) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV57791918; called by muse, mutect2, varscan2
- ASTN2 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1371758701, COSV57772669; called by muse, mutect2, varscan2
- ATMIN | c.1676T>C p.I559T | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs776561312, COSV100214669; called by muse, mutect2, varscan2
- CACNA1B | c.6841G>A p.E2281K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs745875738, COSV53120200; called by muse, mutect2, varscan2
- CACNA2D3 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772419843, COSV55516479; called by muse, mutect2, varscan2
- CAMTA1 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs200762060; called by muse, mutect2, varscan2
- CDADC1 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.817); catalogued as COSV51911764, COSV51912270; called by muse, mutect2
- CENATAC | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57722326; called by muse, mutect2, varscan2
- CHGB | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as rs370206314; called by muse, mutect2, varscan2
- CPAMD8 | c.2658G>A p.M886I (on ENST00000651564; = p.M839I on NM_015692.5) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV71596810; called by muse, mutect2, varscan2
- CSGALNACT1 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.612); catalogued as COSV59979637; called by muse, mutect2, varscan2
- CSMD1 | c.2767G>A p.A923T (on ENST00000520002; = p.A922T on NM_033225.6) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs771033685, COSV59346530, COSV59383954; called by muse, mutect2, varscan2
- CSTF2T | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV58656883; called by muse, mutect2, varscan2
- CYLC1 | c.1304A>T p.K435M | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1228526846, COSV61413459; called by muse, mutect2, varscan2
- CYP2A7 | c.295A>C p.S99R | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394200; called by muse, mutect2, varscan2
- DCAF12L2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs765247772, COSV63581337; called by muse, mutect2, varscan2
- DNAH11 | c.8615G>A p.R2872H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs374342102; called by muse, mutect2, varscan2
- DPP10 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs764618439, COSV59679421; called by muse, mutect2, varscan2
- DYTN | c.1543A>T p.I515F | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1559305138, COSV71752442; called by muse, mutect2, varscan2
- EDA | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.422); catalogued as rs1488012013, COSV65782295; called by muse, mutect2, varscan2
- FAM47C | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs781909617, COSV100792386; called by muse, mutect2, varscan2
- FFAR3 | c.774G>T p.R258S | Missense Mutation (SNP) | VAF 100/1221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771186481, COSV100588232; called by muse, mutect2
- FHL5 | c.384T>A p.F128L | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100459518; called by muse, mutect2
- FLG | c.9890G>T p.S3297I | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV64243885; called by muse, mutect2, varscan2
- FPR1 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59051571; called by muse, mutect2, varscan2
- FZD9 | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.281); catalogued as COSV100750853; called by muse, mutect2
- GGT5 | c.1229+1G>A p.X410_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs372682332; called by muse, mutect2, varscan2
- GREB1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297512255, COSV52180598; called by muse, mutect2, varscan2
- HDC | c.1815G>C p.K605N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV51073402; called by muse, mutect2, varscan2
- HEATR5B | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV99249579; called by muse, mutect2
- HSPD1 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as COSV52099203, COSV52099230; called by muse, mutect2, varscan2
- HUWE1 | c.12331G>A p.G4111R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472859; called by muse, varscan2
- IFI27L2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV99463111; called by muse, mutect2, varscan2
- ITPRID2 | c.2932T>G p.L978V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57473367; called by muse, mutect2
- KCNA10 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571676088, COSV63904890, COSV63905603; called by muse, mutect2, varscan2
- KCNK17 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745795187, COSV64685990; called by muse, mutect2, varscan2
- KCNQ3 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101196287, COSV66467388; called by muse, mutect2, varscan2
- KLHL4 | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.079); catalogued as COSV64144247; called by muse, mutect2, varscan2
- KYAT3 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.118); catalogued as rs377683877; called by muse, mutect2, varscan2
- LAMA4 | c.854G>A p.R285Q (on ENST00000230538 / NM_001105206.3; = p.R278Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as rs1175274886, COSV57900035; called by muse, mutect2, varscan2
- LGALS13 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs968971941, COSV55679743; called by muse, mutect2, varscan2
- MAGEA12 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.988); catalogued as COSV100756957; called by muse, varscan2
- MCC | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as rs773355443, COSV56731277; called by muse, mutect2, varscan2
- MDH1B | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65590343; called by muse, mutect2, varscan2
- MINAR1 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs763878883, COSV59584261, COSV59587078; called by muse, mutect2, varscan2
- MUC16 | c.8568G>C p.E2856D | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67476600; called by muse, mutect2, varscan2
- NCKAP1 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV100720352; called by muse, mutect2, varscan2
- NKD1 | c.500T>G p.V167G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV51692231; called by muse, mutect2, varscan2
- NOP14 | c.741A>T p.K247N | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV58626086; called by muse, mutect2, varscan2
- NPBWR1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs906189485, COSV58696785; called by muse, mutect2, varscan2
- NPC1L1 | c.3045C>G p.F1015L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1347496020, COSV56923752, COSV56926835; called by muse, mutect2, varscan2
- NTNG1 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs939752168, COSV53962757; called by muse, mutect2, varscan2
- NUP58 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs373360958; called by muse, mutect2, varscan2
- ODAPH | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as rs765305769, COSV61141381; called by muse, mutect2, varscan2
- OR10G8 | c.378T>G p.S126R | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV70908783; called by muse, mutect2, varscan2
- OSGEP | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs374503423; called by muse, mutect2, varscan2
- PATJ | c.2560C>G p.H854D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV57165703; called by muse, mutect2, varscan2
- PCLO | c.9174T>G p.I3058M | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.838); catalogued as COSV61645998; called by muse, mutect2, varscan2
- PEG3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1046467329, COSV55638306; called by muse, mutect2, varscan2
- PLG | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51985057, COSV99804803; called by muse, mutect2, varscan2
- PNLIP | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941348581, COSV100981569, COSV65041048; called by muse, mutect2, varscan2
- PPFIA1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs770999735, COSV99557609; called by muse, mutect2, varscan2
- PRRC2C | c.2284A>T p.I762F (on ENST00000367742; = p.I760F on NM_015172.4) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100145462; called by muse, mutect2, varscan2
- PTCD2 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755116275, COSV54651361, COSV54654034, COSV99781895; called by mutect2, varscan2
- PTPN13 | c.2103G>C p.L701F | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV57410827; called by muse, mutect2, varscan2
- RB1CC1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99212373; called by muse, mutect2, varscan2
- RBBP8NL | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs778154623, COSV53349697, COSV53350362; called by muse, mutect2, varscan2
- RBM42 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs538251490, COSV52898131; called by muse, mutect2, varscan2
- SCN11A | c.1820A>C p.K607T | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100181808; called by muse, mutect2, varscan2
- SCN5A | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs969308588, COSV61129762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFRP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55174231; called by muse, mutect2, varscan2
- SIX1 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55959571; called by muse, mutect2, varscan2
- SLC1A6 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs947594885, COSV55668511, COSV55669476; called by muse, mutect2, varscan2
- SPTA1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs759192785, COSV63748349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRCAP | c.9235C>T p.R3079W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs768225785, COSV52675668; called by muse, mutect2, varscan2
- SSC4D | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs199812860, COSV51882943; called by muse, mutect2, varscan2
- TMEM106C | c.600del p.Y201Tfs*14 | Frame Shift Del (DEL) | VAF 35/151 reads (23%) | catalogued as COSV56743027; called by mutect2, pindel, varscan2
- TMPRSS11E | c.416A>C p.Q139P | Missense Mutation (SNP) | VAF 304/640 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV59519882; called by muse, mutect2, varscan2
- TRPV3 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV56792637; called by muse, mutect2, varscan2
- TSHZ2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141167641, COSV61586883; called by muse, mutect2, varscan2
- TUBB | c.1321_1332del p.E441_A444del | In Frame Del (DEL) | VAF 5/37 reads (14%) | catalogued as rs747584215; called by mutect2, varscan2
- UBE2C | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 26/282 reads (9%) | catalogued as COSV54755198; called by muse, mutect2
- UBQLN4 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs753589235, COSV64149700; called by muse, mutect2, varscan2
- UNC13C | c.6448G>A p.G2150R | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs753460509, COSV52876360; called by muse, mutect2, varscan2
- USH2A | c.3595G>A p.E1199K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs776039406, COSV56392769; called by muse, mutect2, varscan2
- WDHD1 | c.2192G>T p.R731L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62214631; called by muse, varscan2
- ZFHX4 | c.7231G>T p.E2411* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV51458544; called by muse, mutect2, varscan2
- ZFR2 | c.2646C>T p.H882= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as rs1380653125, COSV53600320; called by muse, mutect2, varscan2
- ZFYVE26 | c.3686G>A p.S1229N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61330296; called by muse, mutect2, varscan2
- ZNF200 | c.530_536delinsTT p.Y177Ffs*6 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as COSV67724038; called by pindel, varscan2*
- ZNF318 | c.3439del p.D1147Ifs*9 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs1562128912; called by mutect2, pindel, varscan2
- ZNF556 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV56912802; called by muse, mutect2, varscan2
- CHD8 | c.2068_2078delinsGA p.K690_R693delinsE (on ENST00000646647 / NM_001170629.2; = p.K411_R414delinsE on NM_020920.4) | In Frame Del (DEL) | VAF 20/208 reads (10%) | called by pindel, varscan2*
- FOXP1 | c.497_498del p.K166Tfs*3 | Frame Shift Del (DEL) | VAF 71/361 reads (20%) | called by mutect2, pindel, varscan2
- POTED | c.969_971del p.L325del | In Frame Del (DEL) | VAF 28/303 reads (9%) | called by pindel, varscan2
- RTL8A | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- SNX2 | c.66_67dup p.D23Gfs*14 | Frame Shift Ins (INS) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- TAF4 | c.2850del p.D951Ifs*16 | Frame Shift Del (DEL) | VAF 12/96 reads (13%) | called by mutect2, pindel, varscan2
- BLM | c.2361G>A p.K787= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as COSV100757236; called by muse, mutect2
- BOC | c.129G>A p.A43= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs752378926, COSV56349313; called by muse, mutect2, varscan2
- BPIFB1 | c.753G>A p.K251= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV53607274; called by muse, mutect2, varscan2
- CACNA1F | c.3093C>T p.D1031= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs782655905, COSV59903014; called by muse, mutect2, varscan2
- CNOT3 | c.942T>G p.P314= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as COSV55365142; called by muse, mutect2
- CNPY4 | c.513C>T p.Y171= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV53542790; called by muse, mutect2, varscan2
- FAM47C | c.2040G>A p.P680= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs782320093, COSV63727964; called by muse, mutect2, varscan2
- FAT1 | c.8727C>T p.T2909= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs757154932, COSV71674325; called by muse, mutect2, varscan2
- FYB1 | c.198C>A p.V66= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs753081932, COSV60950132; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.24G>T p.L8= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- JUP | c.1932C>T p.Y644= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs201704572, COSV60278766, COSV60280344; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGALS7B | c.132C>T p.G44= | Silent (SNP) | VAF 23/266 reads (9%) | catalogued as rs1168283681, COSV59252091; called by muse, mutect2
- LTBP2 | c.1872C>T p.N624= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs149576879; called by muse, mutect2, varscan2
- MID1 | c.1353C>T p.H451= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs748126421, COSV58196267; called by muse, mutect2, varscan2
- MORC1 | c.2751G>A p.L917= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV51719759; called by muse, mutect2, varscan2
- MYOCD | c.543C>T p.D181= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs368720240, COSV58497356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OVOL2 | c.300G>A p.P100= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1347288527, COSV99602501; called by muse, mutect2
- PCDH17 | c.963G>C p.V321= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100931633, COSV100931722; called by muse, mutect2, varscan2
- PCDHA9 | c.2118G>A p.A706= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV65328491; called by muse, mutect2, varscan2
- PPFIA4 | c.1917G>A p.A639= (on ENST00000447715; = p.A640= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs780463396, COSV55312347; called by muse, mutect2, varscan2
- RHOB | c.510C>G p.V170= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs767483023, COSV99695294; called by mutect2, varscan2
- SART3 | c.2214G>A p.T738= (on ENST00000228284; = p.T720= on NM_014706.4) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs751321190, COSV57208507; called by muse, mutect2, varscan2
- SLC2A5 | c.618G>A p.Q206= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV66237322; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1764G>A p.T588= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs759477767, COSV64854511; called by mutect2, varscan2
- TTN | c.9714G>A p.P3238= (on ENST00000591111; = p.P3192= on NM_003319.4) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs886042397, COSV60164051, COSV60178914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNDC15 | c.507T>C p.S169= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV64380172; called by muse, varscan2
- UTP20 | c.6723C>T p.I2241= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs932857642, COSV55377657; called by muse, mutect2, varscan2
- ZBTB43 | c.102C>T p.D34= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs371516295; called by muse, mutect2, varscan2
- ZNF649 | c.156C>T p.G52= | Silent (SNP) | VAF 51/313 reads (16%) | catalogued as COSV61617208; called by muse, mutect2, varscan2
- ZSCAN31 | c.72A>G p.E24= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100716800, COSV100717027; called by muse, mutect2
- AL132655.6 | chr20:58840535 C>T | 5'Flank (SNP) | VAF 7/61 reads (11%) | catalogued as COSV58339261; called by mutect2, varscan2
- MBD2 | c.702+1951T>A | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56502401; called by muse, mutect2, varscan2
